Surgical pathology report (de-identified scan), TCGA case TCGA-41-6646, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Christiana Healthcare, specimen TCGA-41-6646-01A (Primary Tumor).

[page 1 of 2]
Date Coll: [REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Right frontal mass
- B. Right frontal mass
- C. Right frontal mass

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right frontal mass.

FROZEN SECTION DIAGNOSIS

- FSA) Glioblastoma multiforme. [REDACTED]
- FSB) Right frontal - Predominantly gliotic brain with focal area of glioblastoma present. [REDACTED]

GROSS DESCRIPTION

A. The specimen is received fresh for frozen section labeled "right frontal mass". It consists of two portions of tissue. The first is a sheet of glistening pink fibromembranous tissue measuring 3 x 1.8 x 0.1 cm. The other is a fragment of soft reddish-tan glistening tissue measuring 2 x 1 x 0.7 cm. This portion is bisected and half is submitted for frozen section. A touch preparation is also made. The remaining tissue is submitted in two blocks, following fixation. [REDACTED]

B. The specimen is received fresh for frozen section labeled "right frontal mass". It consists of two fragments of soft white tissue measuring 0.7 x 0.3 x 0.2 cm. in aggregate. A touch preparation is made and the entire specimen is submitted in one block for frozen section. [REDACTED]

C. Received in formalin, labeled "right frontal mass" is a 4.1 x 2.7 x 1.3 cm. aggregate of fragmented focally cauterized tan white-pink tissue. The largest fragment appears to be tumor in association with a portion of dura, the cauterized aspect of which is inked blue. The specimens are sectioned and entirely submitted in three blocks as labeled.

BLOCK SUMMARY: 1 - Smaller fragments; 2, 3 - largest fragment with associated dura.

MICROSCOPIC DESCRIPTION

Microscopic sections of the right frontal mass reveals a Glioblastoma multiforme. The tumor is a high grade diffuse astrocytoma with pleomorphism, mitotic activity, neovascularity and pseudopalisading necrosis. The part B specimen consisted predominantly of gliotic brain with some areas of focal glioblastoma present. The dura is focally infiltrated by tumor.

4x3, 14x2

[page 2 of 2]
DIAGNOSIS

- A. Brain, right frontal, biopsy:
Glioblastoma multiforme (Astrocytoma WHO grade IV).
- B. Brain, right frontal, biopsy:
Predominantly gliotic brain with focal areas of Glioblastoma multiforme present.
- C. Brain, right frontal, resection:
Glioblastoma multiforme (Astrocytoma WHO grade IV).
-

--- End Of Report ---

Source: NCI Genomic Data Commons file 22b3559e-cfba-49bb-94f7-27f245f62e05 (TCGA-41-6646.6B3CF1A0-D385-4211-A68D-6CB8AE1A551F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).